Somatic mutation profile of tumor specimen C3L-02834-03 (aliquot CPT0174510006) from CPTAC case C3L-02834, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 67.5 years (24,663 days).
Specimen C3L-02834-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 795cdb43-386a-4f61-9565-d53dfbfcf173.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02834-31 (Blood Derived Normal), aliquot CPT0175490002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/05a50bad-8f02-4cf9-b7e6-64dfa88a9ae7

The open-access MAF lists 327 somatic variants for this specimen: 228 protein-altering or splice-affecting, 60 silent, 39 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 188, Silent 60, Nonsense Mutation 22, RNA 12, Intron 12, Frame Shift Del 8, 5'UTR 6, 3'UTR 5, Splice Site 4, Splice Region 3, Frame Shift Ins 3, 5'Flank 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KMT2D | c.4485C>A p.Y1495* | Nonsense Mutation (SNP) | VAF 24/262 reads (9%) | catalogued as rs574622908, COSV56474587, COSV56475240; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.782+1G>T p.X261_splice | Splice Site (SNP) | VAF 73/170 reads (43%) | hotspot (GDC flag); catalogued as rs1555525429, COSV52665287, COSV52673806, COSV52698978; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- ABCG1 | c.1987C>T p.R663C | Missense Mutation (SNP) | VAF 28/394 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1302262582, COSV59200688, COSV59207718; called by muse, mutect2
- ADAT1 | c.1191C>T p.A397= | Splice Region (SNP) | VAF 24/193 reads (12%) | catalogued as rs577366663; called by muse, mutect2, varscan2
- ADCK2 | c.266C>T p.P89L | Missense Mutation (SNP) | VAF 25/144 reads (17%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs1355854417; called by muse, mutect2, varscan2
- ANK2 | c.8393G>A p.G2798D | Missense Mutation (SNP) | VAF 38/226 reads (17%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.003); catalogued as rs1164213516, COSV52144213; called by muse, mutect2, varscan2
- APOH | c.595G>T p.E199* | Nonsense Mutation (SNP) | VAF 8/120 reads (7%) | catalogued as COSV52771137; called by muse, mutect2
- ARHGEF10L | c.2689G>T p.G897W | Missense Mutation (SNP) | VAF 35/163 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51432039; called by muse, mutect2, varscan2
- ASS1 | c.1003C>T p.R335C | Missense Mutation (SNP) | VAF 75/663 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.331); catalogued as rs373514077, COSV100752854; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP7B | c.3580A>G p.I1194V | Missense Mutation (SNP) | VAF 139/535 reads (26%) | SIFT tolerated (0.52); PolyPhen benign (0.07); catalogued as rs745679410; called by muse, mutect2, varscan2
- BTAF1 | c.4405A>G p.I1469V | Missense Mutation (SNP) | VAF 78/230 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as rs375960243; called by muse, mutect2, varscan2
- CCKAR | c.966C>A p.F322L | Missense Mutation (SNP) | VAF 47/446 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs549621504; called by muse, mutect2, varscan2
- CDH23 | c.7924G>A p.E2642K | Missense Mutation (SNP) | VAF 53/143 reads (37%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.78); catalogued as COSV99821987; called by muse, mutect2, varscan2
- CES1 | c.859C>T p.R287* | Nonsense Mutation (SNP) | VAF 233/702 reads (33%) | catalogued as rs144078935; called by muse, varscan2
- CFHR4 | c.249C>A p.C83* (on ENST00000367416 / NM_001201551.2; = p.C84* on NM_006684.5) | Nonsense Mutation (SNP) | VAF 14/104 reads (13%) | catalogued as COSV52225316; called by muse, mutect2
- CNTNAP5 | c.3247G>T p.E1083* | Nonsense Mutation (SNP) | VAF 19/152 reads (13%) | catalogued as COSV70517960; called by muse, mutect2, varscan2
- COL22A1 | c.3182C>G p.S1061C | Missense Mutation (SNP) | VAF 27/185 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.552); catalogued as COSV57327938; called by muse, mutect2, varscan2
- CPS1 | c.1786G>T p.G596C | Missense Mutation (SNP) | VAF 29/366 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.681); catalogued as COSV99244065; called by muse, mutect2
- DISP3 | c.3429G>A p.W1143* | Nonsense Mutation (SNP) | VAF 56/242 reads (23%) | catalogued as COSV53834204; called by muse, mutect2, varscan2
- DPPA4 | c.493C>A p.P165T | Missense Mutation (SNP) | VAF 131/505 reads (26%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.593); catalogued as COSV59509238; called by muse, mutect2, varscan2
- DYM | c.606G>C p.L202F | Missense Mutation (SNP) | VAF 59/216 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.425); catalogued as COSV53986311, COSV53990430; called by muse, mutect2, varscan2
- EFCAB2 | c.22C>T p.R8W | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1408984168; called by muse, mutect2, varscan2
- EXOSC1 | c.65C>T p.P22L | Missense Mutation (SNP) | VAF 73/242 reads (30%) | SIFT tolerated (0.33); PolyPhen benign (0.02); catalogued as rs147036130; called by muse, mutect2, varscan2
- FOXE3 | c.416C>T p.P139L | Missense Mutation (SNP) | VAF 128/696 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs554320597; called by muse, mutect2, varscan2
- GNAZ | c.928G>T p.D310Y | Missense Mutation (SNP) | VAF 68/309 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as COSV50738143; called by muse, mutect2, varscan2
- H4-16 | c.118C>T p.R40* | Nonsense Mutation (SNP) | VAF 33/384 reads (9%) | catalogued as COSV100797673; called by muse, mutect2
- HJURP | c.1532C>T p.A511V | Missense Mutation (SNP) | VAF 71/316 reads (22%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as rs1354958271; called by muse, mutect2, varscan2
- INHBA | c.907del p.H303Tfs*56 | Frame Shift Del (DEL) | VAF 27/85 reads (32%) | catalogued as COSV99637607; called by mutect2, pindel, varscan2
- INPP4A | c.2062G>T p.G688C (on ENST00000074304 / NM_001134224.1; = p.G649C on NM_001566.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 121/500 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50790190, COSV50859307; called by muse, mutect2, varscan2
- JCAD | c.3235G>A p.G1079S | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0.009); catalogued as rs375563520; called by muse, mutect2
- KHSRP | c.1561G>A p.G521R | Missense Mutation (SNP) | VAF 28/246 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.738); catalogued as COSV101231184; called by muse, mutect2, varscan2
- KIF18B | c.1315G>C p.E439Q (on ENST00000593135 / NM_001265577.2; = p.E451Q on NM_001264573.2) | Missense Mutation (SNP) | VAF 23/238 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs550488305; called by muse, mutect2
- KL | c.1348G>A p.V450M | Missense Mutation (SNP) | VAF 27/373 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV101199245; called by muse, mutect2
- KRT18 | c.898A>G p.R300G | Missense Mutation (SNP) | VAF 65/658 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs1185499795; called by muse, mutect2
- LITAF | c.269G>T p.R90L | Missense Mutation (SNP) | VAF 28/248 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.172); catalogued as rs200789696; called by muse, mutect2, varscan2
- MAP6 | c.730C>T p.P244S | Missense Mutation (SNP) | VAF 15/150 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.614); catalogued as rs1461038944; called by muse, mutect2
- MAST2 | c.324G>T p.S108= | Splice Region (SNP) | VAF 4/21 reads (19%) | catalogued as COSV100788377, COSV63619584; called by muse, varscan2
- MGAT4B | c.1074del p.I359Sfs*24 | Frame Shift Del (DEL) | VAF 109/307 reads (36%) | catalogued as COSV99482307; called by mutect2, pindel, varscan2
- NBEA | c.7688G>T p.R2563L | Missense Mutation (SNP) | VAF 16/212 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100085566; called by muse, mutect2
- NCKAP1L | c.1594C>A p.L532M | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.77); catalogued as COSV99515261; called by muse, mutect2, varscan2
- NEB | c.18794G>C p.R6265T | Missense Mutation (SNP) | VAF 78/291 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs759929179; called by muse, mutect2, varscan2
- NRXN1 | c.240G>T p.E80D | Missense Mutation (SNP) | VAF 48/135 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.123); catalogued as COSV68026601; called by muse, mutect2, varscan2
- OBSCN | c.19804G>C p.D6602H | Missense Mutation (SNP) | VAF 35/182 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63479912; called by muse, mutect2, varscan2
- OR13F1 | c.18G>A p.W6* | Nonsense Mutation (SNP) | VAF 24/52 reads (46%) | catalogued as rs569833689; called by muse, mutect2, varscan2
- OR2T6 | c.127G>T p.G43W | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); catalogued as COSV100861607; called by muse, mutect2, varscan2
- OR56A1 | c.358G>A p.V120I | Missense Mutation (SNP) | VAF 27/301 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.02); catalogued as rs531071507; called by muse, mutect2
- OR56A4 | c.152T>A p.L51H | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); catalogued as COSV58111967; called by muse, mutect2, varscan2
- OR5P3 | c.334T>C p.C112R | Missense Mutation (SNP) | VAF 86/374 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as COSV100103126; called by muse, mutect2, varscan2
- OR6K2 | c.631G>T p.A211S | Missense Mutation (SNP) | VAF 32/208 reads (15%) | SIFT tolerated (0.71); PolyPhen benign (0.041); catalogued as COSV100656736; called by muse, mutect2, varscan2
- OR8K5 | c.903C>A p.F301L | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as COSV57891082; called by muse, mutect2, varscan2
- OR9Q2 | c.380G>T p.C127F | Missense Mutation (SNP) | VAF 40/256 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); catalogued as COSV100285489; called by muse, mutect2, varscan2
- PCDH17 | c.119G>T p.R40M | Missense Mutation (SNP) | VAF 36/446 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.657); catalogued as rs774440820, COSV100931408; called by muse, mutect2
- POTEB3 | c.17G>C p.C6S | Missense Mutation (SNP) | VAF 38/490 reads (8%) | SIFT tolerated, low confidence (0.91); PolyPhen benign (0.152); catalogued as rs1238172838; called by muse, mutect2
- PSG2 | c.866C>A p.P289H | Missense Mutation (SNP) | VAF 75/334 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.948); catalogued as rs367697086; called by muse, mutect2, varscan2
- PSKH2 | c.1055G>T p.G352V | Missense Mutation (SNP) | VAF 62/341 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.127); catalogued as COSV99404993; called by muse, mutect2, varscan2
- PTH2R | c.1516C>A p.P506T | Missense Mutation (SNP) | VAF 31/122 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs956794027; called by muse, mutect2, varscan2
- PTPRD | c.4947+1G>T p.X1649_splice | Splice Site (SNP) | VAF 8/58 reads (14%) | catalogued as COSV61973086; called by muse, mutect2, varscan2
- PZP | c.82C>T p.P28S | Missense Mutation (SNP) | VAF 39/125 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.607); catalogued as rs1193422527; called by muse, mutect2, varscan2
- RAD9A | c.439G>T p.A147S | Missense Mutation (SNP) | VAF 41/135 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.768); catalogued as rs199689239; called by muse, mutect2, varscan2
- SERPINA6 | c.826G>A p.V276I | Missense Mutation (SNP) | VAF 144/296 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.276); catalogued as rs1436945752, COSV58585717; called by muse, mutect2, varscan2
- SIGLEC8 | c.704C>A p.T235K | Missense Mutation (SNP) | VAF 66/344 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.809); catalogued as COSV58472567; called by muse, mutect2, varscan2
- SV2C | c.958C>T p.R320C | Missense Mutation (SNP) | VAF 19/244 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1394622051, COSV59231203; called by muse, mutect2
- TBC1D10C | c.704C>A p.P235Q | Missense Mutation (SNP) | VAF 82/256 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56701833; called by muse, mutect2, varscan2
- TECRL | c.899G>C p.C300S | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67089817; called by muse, mutect2, varscan2
- TECTA | c.2452G>T p.E818* | Nonsense Mutation (SNP) | VAF 103/347 reads (30%) | catalogued as COSV99879478; called by muse, mutect2, varscan2
- TMPRSS9 | c.2759C>G p.P920R (on ENST00000648592; = p.P886R on NM_182973.2) | Missense Mutation (SNP) | VAF 63/243 reads (26%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.757); catalogued as rs1436627400; called by muse, mutect2, varscan2
- TRPA1 | c.778G>T p.D260Y | Missense Mutation (SNP) | VAF 39/270 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as COSV51578561; called by muse, mutect2, varscan2
- UCP1 | c.703G>A p.V235I | Missense Mutation (SNP) | VAF 54/296 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.123); catalogued as rs1446806315; called by muse, mutect2, varscan2
- VAV3 | c.1736G>C p.R579P | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV58381372; called by muse, mutect2, varscan2
- VGF | c.1751G>T p.R584L | Missense Mutation (SNP) | VAF 29/324 reads (9%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.011); catalogued as rs771527523, COSV99972816; called by muse, mutect2
- ZNF534 | c.1492A>G p.R498G (on ENST00000332323 / NM_001143939.3; = p.R485G on NM_001143938.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.446); catalogued as rs779528295, COSV56514589; called by muse, mutect2, varscan2
- ZNF578 | c.1246C>A p.R416S | Missense Mutation (SNP) | VAF 47/287 reads (16%) | SIFT tolerated (0.83); PolyPhen benign (0.334); catalogued as COSV69736048, COSV69736762; called by muse, mutect2, varscan2
- ZNF668 | c.742G>C p.A248P | Missense Mutation (SNP) | VAF 24/411 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.144); catalogued as rs777499105; called by muse, mutect2
- A2M | c.373G>T p.E125* | Nonsense Mutation (SNP) | VAF 20/148 reads (14%) | called by muse, mutect2, varscan2
- AASS | c.2017G>T p.V673F | Missense Mutation (SNP) | VAF 114/324 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.835); called by muse, mutect2, varscan2
- ABCB5 | c.3457G>T p.G1153* (on ENST00000404938 / NM_001163941.2; = p.G708* on NM_178559.6) | Nonsense Mutation (SNP) | VAF 62/174 reads (36%) | called by muse, mutect2, varscan2
- ACOX3 | c.1926del p.D642Efs*2 | Frame Shift Del (DEL) | VAF 36/274 reads (13%) | called by mutect2, pindel, varscan2
- ADAMTS5 | c.1163G>A p.C388Y | Missense Mutation (SNP) | VAF 63/288 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AGA | c.946G>A p.A316T | Missense Mutation (SNP) | VAF 16/238 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- AGT | c.1017C>A p.S339R | Missense Mutation (SNP) | VAF 98/505 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- ANKS1B | c.3415G>T p.D1139Y (on ENST00000547776 / NM_152788.4; = p.D305Y on NM_020140.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/112 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANKUB1 | c.1423C>G p.L475V | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.243); called by muse, mutect2
- ARHGAP40 | c.1070C>A p.P357Q | Missense Mutation (SNP) | VAF 39/201 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ASTE1 | c.79A>C p.K27Q | Missense Mutation (SNP) | VAF 59/178 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.5); called by muse, mutect2, varscan2
- ASXL3 | c.2531C>G p.T844S | Missense Mutation (SNP) | VAF 112/351 reads (32%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- BCS1L | c.320+3A>T | Splice Region (SNP) | VAF 116/437 reads (27%) | called by muse, mutect2, varscan2
- BSPH1 | c.216C>G p.N72K | Missense Mutation (SNP) | VAF 22/150 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- BTLA | c.488del p.G163Dfs*16 | Frame Shift Del (DEL) | VAF 48/212 reads (23%) | called by mutect2, pindel, varscan2
- CAPN6 | c.1132C>A p.R378S | Missense Mutation (SNP) | VAF 23/173 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- CAPN9 | c.103G>T p.E35* | Nonsense Mutation (SNP) | VAF 109/451 reads (24%) | called by muse, mutect2, varscan2
- CBLB | c.951T>A p.F317L | Missense Mutation (SNP) | VAF 113/474 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- CCDC168 | c.16447G>T p.V5483L | Missense Mutation (SNP) | VAF 48/205 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- CEP63 | c.1354A>C p.S452R | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- CES1 | c.451A>T p.T151S | Missense Mutation (SNP) | VAF 81/1282 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.03); called by muse, mutect2
- CLCA4 | c.1180C>G p.Q394E | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.029); called by muse, varscan2
- CLDND2 | c.103C>A p.Q35K | Missense Mutation (SNP) | VAF 43/263 reads (16%) | SIFT tolerated (0.73); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- COL6A3 | c.6656G>T p.G2219V | Missense Mutation (SNP) | VAF 48/480 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CSMD1 | c.9448C>A p.Q3150K (on ENST00000520002; = p.Q3149K on NM_033225.6) | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.949); called by muse, mutect2
- CSMD3 | c.2374A>G p.T792A (on ENST00000297405 / NM_001363185.1; = p.T688A on NM_052900.3) | Missense Mutation (SNP) | VAF 73/199 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.466); called by muse, mutect2, varscan2
- CUX2 | c.2959C>A p.P987T | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT tolerated (0.64); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DLX5 | c.740C>A p.S247Y | Missense Mutation (SNP) | VAF 70/238 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- DNAI3 | c.877del p.Q293Kfs*5 | Frame Shift Del (DEL) | VAF 14/78 reads (18%) | called by mutect2, pindel
- DNAJC19 | c.83A>T p.H28L | Missense Mutation (SNP) | VAF 60/694 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0.062); called by muse, mutect2
- DST | c.6767C>T p.P2256L | Missense Mutation (SNP) | VAF 88/223 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- DYNC2LI1 | c.161G>T p.R54I | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2
- DYNLRB2 | c.189G>C p.Q63H | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.112); called by muse, mutect2
- EPHA2 | c.1979T>G p.F660C | Missense Mutation (SNP) | VAF 42/475 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- EPHA8 | c.690G>T p.R230S | Missense Mutation (SNP) | VAF 50/246 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ERICH3 | c.2456C>A p.P819Q | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ERVV-2 | c.1270T>A p.Y424N | Missense Mutation (SNP) | VAF 34/143 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- EXOC2 | c.248G>T p.R83I | Missense Mutation (SNP) | VAF 59/135 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- FABP2 | c.7T>A p.F3I | Missense Mutation (SNP) | VAF 17/147 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- FAM107B | c.95G>A p.G32E | Missense Mutation (SNP) | VAF 19/162 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FANCD2 | c.2567C>A p.T856N | Missense Mutation (SNP) | VAF 63/192 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- FAT3 | c.11234G>T p.G3745V | Missense Mutation (SNP) | VAF 23/125 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FBLN2 | c.970G>T p.A324S | Missense Mutation (SNP) | VAF 174/526 reads (33%) | SIFT tolerated (0.55); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- FRMPD3 | c.1614del p.S538Rfs*46 | Frame Shift Del (DEL) | VAF 62/305 reads (20%) | called by mutect2, pindel, varscan2
- FSCN1 | c.172G>T p.A58S | Missense Mutation (SNP) | VAF 56/354 reads (16%) | SIFT tolerated (0.78); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FTSJ1 | c.511C>T p.Q171* | Nonsense Mutation (SNP) | VAF 48/520 reads (9%) | called by muse, mutect2
- GALC | c.778G>A p.A260T | Missense Mutation (SNP) | VAF 92/264 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, varscan2
- GAREM2 | c.1283C>A p.P428H | Missense Mutation (SNP) | VAF 41/308 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GRID2IP | c.247C>A p.P83T | Missense Mutation (SNP) | VAF 33/180 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- HCK | c.494T>C p.L165P | Missense Mutation (SNP) | VAF 48/320 reads (15%) | SIFT tolerated (0.48); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- HCN1 | c.2587C>A p.P863T | Missense Mutation (SNP) | VAF 29/372 reads (8%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); called by muse, mutect2
- HEPH | c.3319A>T p.M1107L (on ENST00000343002; = p.M840L on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 84/450 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- HJURP | c.354G>T p.E118D | Missense Mutation (SNP) | VAF 23/265 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- HR | c.1796del p.C599Sfs*61 | Frame Shift Del (DEL) | VAF 76/403 reads (19%) | called by mutect2, pindel, varscan2
- HS3ST4 | c.1235G>T p.S412I | Missense Mutation (SNP) | VAF 52/656 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- HTT | c.3868G>T p.V1290F | Missense Mutation (SNP) | VAF 42/194 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- IFT88 | c.1663G>T p.A555S (on ENST00000319980 / NM_001318493.2; = p.A546S on NM_006531.5 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/159 reads (21%) | SIFT tolerated (0.73); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- IGF1R | c.1936G>T p.V646L | Missense Mutation (SNP) | VAF 46/207 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.228); called by muse, mutect2, varscan2
- ITSN1 | c.3763G>A p.D1255N | Missense Mutation (SNP) | VAF 39/148 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- JPH3 | c.2123T>C p.L708P | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.006); called by muse, mutect2
- KALRN | c.6251G>T p.C2084F (on ENST00000360013 / NM_001024660.4; = p.C387F on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 64/251 reads (25%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- KALRN | c.8692A>G p.S2898G (on ENST00000360013 / NM_001024660.4; = p.S1201G on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 51/392 reads (13%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- KCNH8 | c.2173G>T p.V725F | Missense Mutation (SNP) | VAF 37/398 reads (9%) | SIFT tolerated (0.81); PolyPhen benign (0.003); called by muse, mutect2
- KCNN1 | c.82C>A p.P28T | Missense Mutation (SNP) | VAF 42/158 reads (27%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- KCTD13 | c.20G>T p.G7V | Missense Mutation (SNP) | VAF 40/118 reads (34%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- KIF5A | c.168C>A p.N56K | Missense Mutation (SNP) | VAF 56/538 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.221); called by muse, mutect2, varscan2
- KLHL4 | c.790C>A p.L264M | Missense Mutation (SNP) | VAF 18/208 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.547); called by muse, mutect2
- KRIT1 | c.512C>T p.S171F | Missense Mutation (SNP) | VAF 17/300 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); called by muse, mutect2
- KYAT3 | c.1357A>T p.K453* | Nonsense Mutation (SNP) | VAF 20/84 reads (24%) | called by muse, mutect2, varscan2
- LAMA3 | c.5791A>G p.K1931E (on ENST00000313654 / NM_198129.4; = p.K322E on NM_000227.6) | Missense Mutation (SNP) | VAF 22/353 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.047); called by muse, mutect2
- LAT2 | c.683A>G p.D228G | Missense Mutation (SNP) | VAF 32/184 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LCMT2 | c.1711G>T p.G571* | Nonsense Mutation (SNP) | VAF 36/166 reads (22%) | called by muse, mutect2, varscan2
- LONP2 | c.1612C>T p.P538S | Missense Mutation (SNP) | VAF 56/159 reads (35%) | SIFT tolerated (0.44); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- LRCH1 | c.412G>C p.A138P | Missense Mutation (SNP) | VAF 34/161 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.433); called by muse, mutect2, varscan2
- LRRC4C | c.241C>A p.L81M | Missense Mutation (SNP) | VAF 57/206 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LRRIQ4 | c.1491C>A p.Y497* | Nonsense Mutation (SNP) | VAF 80/242 reads (33%) | called by muse, mutect2, varscan2
- MAGEB2 | c.339G>T p.R113S | Missense Mutation (SNP) | VAF 66/264 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- MAN1A2 | c.1328C>G p.T443S | Missense Mutation (SNP) | VAF 21/133 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- MAX | c.292C>T p.Q98* | Nonsense Mutation (SNP) | VAF 292/700 reads (42%) | called by muse, mutect2, varscan2
- MBOAT1 | c.747G>T p.L249F | Missense Mutation (SNP) | VAF 33/98 reads (34%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- MED16 | c.2399G>T p.R800M | Missense Mutation (SNP) | VAF 35/156 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MET | c.3020_3028+20del p.X1007_splice | Splice Site (DEL) | VAF 99/294 reads (34%) | called by mutect2, pindel*
- MNDA | c.808G>C p.D270H | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.744); called by muse, mutect2, varscan2
- MROH5 | c.1579C>G p.Q527E | Missense Mutation (SNP) | VAF 118/435 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- MRPL51 | c.58G>T p.A20S | Missense Mutation (SNP) | VAF 18/238 reads (8%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.005); called by muse, mutect2
- MTA2 | c.677C>T p.S226F | Missense Mutation (SNP) | VAF 16/131 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- MTARC2 | c.758G>T p.W253L | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MUC16 | c.17446A>G p.R5816G | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MYG1 | c.172G>T p.E58* | Nonsense Mutation (SNP) | VAF 36/314 reads (11%) | called by muse, mutect2, varscan2
- MYL12A | c.121G>T p.D41Y | Missense Mutation (SNP) | VAF 44/183 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYOCD | c.2398G>T p.A800S | Missense Mutation (SNP) | VAF 17/177 reads (10%) | SIFT tolerated (0.92); PolyPhen benign (0); called by muse, mutect2
- NCOA6 | c.4768A>T p.T1590S | Missense Mutation (SNP) | VAF 14/119 reads (12%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0); called by muse, mutect2, varscan2
- NLRP10 | c.1111G>T p.G371C | Missense Mutation (SNP) | VAF 49/141 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NMNAT3 | c.614T>A p.I205N (on ENST00000296202 / NM_001320512.1; = p.I168N on NM_178177.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/480 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- NUP54 | c.944A>T p.D315V | Missense Mutation (SNP) | VAF 13/157 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); called by muse, mutect2
- NXF1 | c.523G>T p.V175F | Missense Mutation (SNP) | VAF 18/274 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.43); called by muse, mutect2
- OR1L6 | c.355C>A p.L119M (on ENST00000373684; = p.L83M on NM_001004453.2) | Missense Mutation (SNP) | VAF 123/352 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR4C11 | c.559T>G p.C187G | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR56A3 | c.863C>A p.P288H | Missense Mutation (SNP) | VAF 13/232 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- ORAI1 | c.106del p.D36Tfs*28 | Frame Shift Del (DEL) | VAF 66/238 reads (28%) | called by mutect2, varscan2
- OTOGL | c.5738G>T p.C1913F (on ENST00000547103; = p.C1904F on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/294 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PAMR1 | c.2057T>A p.M686K (on ENST00000619888 / NM_001001991.3; = p.M703K on NM_015430.4) | Missense Mutation (SNP) | VAF 55/339 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- PAX1 | c.1103G>T p.C368F | Missense Mutation (SNP) | VAF 63/301 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PAX3 | c.958+2T>G p.X320_splice | Splice Site (SNP) | VAF 86/310 reads (28%) | called by muse, mutect2, varscan2
- PEX5L | c.249T>A p.D83E | Missense Mutation (SNP) | VAF 38/183 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PIKFYVE | c.103C>T p.P35S | Missense Mutation (SNP) | VAF 16/204 reads (8%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); called by muse, mutect2
- PLCB1 | c.560C>G p.T187S | Missense Mutation (SNP) | VAF 33/168 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- POLE | c.3751T>C p.W1251R | Missense Mutation (SNP) | VAF 115/456 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- PPM1G | c.1606A>T p.N536Y | Missense Mutation (SNP) | VAF 125/336 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- PRPF31 | c.70G>T p.G24W | Missense Mutation (SNP) | VAF 39/321 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.552); called by muse, mutect2, varscan2
- PTPRB | c.3827C>T p.S1276F | Missense Mutation (SNP) | VAF 55/168 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RBFOX1 | c.499G>A p.A167T | Missense Mutation (SNP) | VAF 31/189 reads (16%) | SIFT tolerated (0.5); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- RBM19 | c.730G>T p.E244* | Nonsense Mutation (SNP) | VAF 59/165 reads (36%) | called by muse, mutect2, varscan2
- RCOR3 | c.1051C>A p.Q351K | Missense Mutation (SNP) | VAF 81/450 reads (18%) | SIFT tolerated (0.72); PolyPhen benign (0); called by muse, mutect2, varscan2
- RGPD3 | c.123dup p.Y42Ifs*2 | Frame Shift Ins (INS) | VAF 9/64 reads (14%) | called by mutect2, pindel, varscan2
- ROBO3 | c.1265A>T p.Y422F | Missense Mutation (SNP) | VAF 57/224 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RPN1 | c.1037G>T p.G346V | Missense Mutation (SNP) | VAF 44/199 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SERPINF1 | c.290A>T p.E97V | Missense Mutation (SNP) | VAF 131/364 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- SETBP1 | c.1104A>C p.K368N | Missense Mutation (SNP) | VAF 40/270 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- SH3RF3 | c.1150G>T p.A384S | Missense Mutation (SNP) | VAF 57/440 reads (13%) | SIFT tolerated (0.56); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- SKOR1 | c.1888A>T p.S630C | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC9A4 | c.466G>T p.G156C | Missense Mutation (SNP) | VAF 130/332 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- SLC9A6 | c.1661G>T p.G554V | Missense Mutation (SNP) | VAF 169/525 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- SOX5 | c.259C>T p.H87Y | Missense Mutation (SNP) | VAF 32/167 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- SULF2 | c.8C>A p.P3H | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- SURF2 | c.205C>T p.P69S | Missense Mutation (SNP) | VAF 36/123 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SVEP1 | c.9368G>T p.G3123V | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SYN2 | c.152C>A p.P51H | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (0.05); PolyPhen benign (0.388); called by mutect2, varscan2
- TAF1 | c.5183G>T p.S1728I (on ENST00000373790 / NM_138923.4; = p.S1749I on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/154 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- TAF7L | c.924C>A p.S308R | Missense Mutation (SNP) | VAF 28/125 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- TFE3 | c.735C>G p.N245K | Missense Mutation (SNP) | VAF 51/137 reads (37%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.683); called by muse, mutect2, varscan2
- TIMM29 | c.46G>T p.E16* | Nonsense Mutation (SNP) | VAF 14/158 reads (9%) | called by muse, mutect2
- TM7SF3 | c.1106T>A p.F369Y | Missense Mutation (SNP) | VAF 20/200 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- TMEM219 | c.458C>G p.S153C | Missense Mutation (SNP) | VAF 26/472 reads (6%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.526); called by muse, mutect2
- TMEM63B | c.997A>T p.I333F | Missense Mutation (SNP) | VAF 59/116 reads (51%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- TMEM81 | c.353G>T p.R118L | Missense Mutation (SNP) | VAF 34/219 reads (16%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.671); called by muse, mutect2, varscan2
- TNRC18 | c.8065C>T p.P2689S | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TOMM70 | c.926A>T p.N309I | Missense Mutation (SNP) | VAF 51/214 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- TRIM56 | c.1552C>T p.P518S | Missense Mutation (SNP) | VAF 25/177 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- TSHZ3 | c.1465G>A p.D489N | Missense Mutation (SNP) | VAF 51/380 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TTC24 | c.1200C>A p.D400E | Missense Mutation (SNP) | VAF 50/263 reads (19%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TTC6 | c.2170A>T p.I724F | Missense Mutation (SNP) | VAF 42/90 reads (47%) | SIFT tolerated (0.73); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- UGT3A2 | c.900G>C p.L300F | Missense Mutation (SNP) | VAF 33/472 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.29); called by muse, mutect2
- UNC80 | c.8636A>T p.Q2879L | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- USH2A | c.9232T>C p.S3078P | Missense Mutation (SNP) | VAF 33/326 reads (10%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- VAV2 | c.1001A>T p.Q334L (on ENST00000371850 / NM_001134398.2; = p.Q329L on NM_003371.4) | Missense Mutation (SNP) | VAF 53/183 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZAN | c.7257C>A p.Y2419* | Nonsense Mutation (SNP) | VAF 35/164 reads (21%) | called by muse, mutect2, varscan2
- ZDHHC11 | c.710G>T p.G237V | Missense Mutation (SNP) | VAF 85/922 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.158); called by muse, mutect2
- ZFPM1 | c.686C>A p.S229Y | Missense Mutation (SNP) | VAF 22/214 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- ZNF423 | c.2896C>G p.H966D (on ENST00000563137 / NM_001379286.1; = p.H958D on NM_015069.4) | Missense Mutation (SNP) | VAF 45/356 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.237); called by muse, mutect2, varscan2
- ZNF575 | c.447C>A p.C149* | Nonsense Mutation (SNP) | VAF 16/130 reads (12%) | called by muse, varscan2
- ZNF735 | c.1140dup p.Y381Ifs*4 | Frame Shift Ins (INS) | VAF 85/289 reads (29%) | called by mutect2, varscan2
- ZNF735 | c.1141delinsAA p.Y381Kfs*4 | Frame Shift Ins (INS) | VAF 53/321 reads (17%) | called by mutect2*, pindel, varscan2*
- ZNF852 | c.610G>T p.V204F | Missense Mutation (SNP) | VAF 27/293 reads (9%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- ZXDC | c.2275G>T p.A759S | Missense Mutation (SNP) | VAF 32/179 reads (18%) | SIFT tolerated (0.38); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- A2M | c.1869A>T p.P623= | Silent (SNP) | VAF 12/111 reads (11%) | called by muse, mutect2, varscan2
- ABCB6 | c.1953G>C p.G651= | Silent (SNP) | VAF 18/145 reads (12%) | called by muse, mutect2, varscan2
- ACSM2B | c.606C>A p.S202= | Silent (SNP) | VAF 75/180 reads (42%) | called by muse, mutect2, varscan2
- ADARB1 | c.339G>T p.V113= | Silent (SNP) | VAF 28/186 reads (15%) | called by muse, mutect2, varscan2
- ADD2 | c.15G>T p.T5= | Silent (SNP) | VAF 9/102 reads (9%) | catalogued as COSV52456589; called by muse, mutect2
- ALB | c.606G>T p.L202= | Silent (SNP) | VAF 31/219 reads (14%) | called by muse, mutect2, varscan2
- ALDH1L1 | c.340C>A p.R114= | Silent (SNP) | VAF 28/100 reads (28%) | called by muse, mutect2, varscan2
- BOD1L2 | c.69C>T p.G23= | Silent (SNP) | VAF 12/73 reads (16%) | catalogued as rs1411518031; called by muse, mutect2, varscan2
- CCDC17 | c.666G>T p.L222= | Silent (SNP) | VAF 34/181 reads (19%) | called by muse, mutect2, varscan2
- CDH10 | c.2022C>A p.T674= | Silent (SNP) | VAF 118/856 reads (14%) | catalogued as rs760760327, COSV52586615; called by muse, mutect2, varscan2
- CFAP47 | c.102G>T p.S34= | Silent (SNP) | VAF 48/280 reads (17%) | catalogued as rs762888297; called by muse, mutect2, varscan2
- CHST7 | c.1086G>T p.A362= | Silent (SNP) | VAF 68/338 reads (20%) | called by muse, mutect2, varscan2
- CPZ | c.792C>T p.Y264= (on ENST00000360986 / NM_001014447.3; = p.Y253= on NM_003652.3) | Silent (SNP) | VAF 65/309 reads (21%) | catalogued as rs200227054; called by muse, mutect2, varscan2
- CRHR2 | c.171A>G p.G57= | Silent (SNP) | VAF 21/316 reads (7%) | called by muse, mutect2
- CSRNP3 | c.456A>T p.T152= | Silent (SNP) | VAF 26/169 reads (15%) | called by muse, mutect2
- DAZAP1 | c.1143G>T p.S381= | Silent (SNP) | VAF 18/148 reads (12%) | called by muse, mutect2, varscan2
- DCAF8L1 | c.606A>T p.I202= | Silent (SNP) | VAF 64/329 reads (19%) | called by muse, mutect2, varscan2
- DPYS | c.192C>T p.I64= | Silent (SNP) | VAF 34/472 reads (7%) | called by muse, mutect2
- ERICH3 | c.3762G>T p.L1254= | Silent (SNP) | VAF 59/286 reads (21%) | called by muse, mutect2, varscan2
- ESYT2 | c.375C>T p.P125= (on ENST00000613624; = p.P49= on NM_020728.3) | Silent (SNP) | VAF 189/453 reads (42%) | called by muse, mutect2, varscan2
- FBRSL1 | c.201G>T p.P67= | Silent (SNP) | VAF 27/72 reads (38%) | catalogued as rs1435588361; called by muse, mutect2, varscan2
- GABRB3 | c.675C>T p.F225= | Silent (SNP) | VAF 47/395 reads (12%) | catalogued as rs201004195; ClinVar: likely benign; called by muse, mutect2, varscan2
- GPR87 | c.171C>A p.I57= | Silent (SNP) | VAF 72/275 reads (26%) | called by muse, mutect2, varscan2
- GRIN2A | c.4359G>T p.V1453= | Silent (SNP) | VAF 41/174 reads (24%) | called by muse, mutect2, varscan2
- HDAC9 | c.522G>A p.K174= | Silent (SNP) | VAF 18/71 reads (25%) | called by muse, mutect2, varscan2
- HYDIN | c.2160C>A p.L720= | Silent (SNP) | VAF 76/215 reads (35%) | called by muse, mutect2, varscan2
- IGHV4-59 | c.177C>T p.P59= | Silent (SNP) | VAF 57/1312 reads (4%) | called by muse, mutect2
- IGSF9B | c.1701G>A p.L567= | Silent (SNP) | VAF 30/416 reads (7%) | called by muse, mutect2
- KIFC3 | c.2298C>T p.R766= | Silent (SNP) | VAF 72/217 reads (33%) | called by muse, mutect2, varscan2
- LRP1B | c.12006C>T p.T4002= | Silent (SNP) | VAF 49/415 reads (12%) | called by muse, mutect2, varscan2
- LY75-CD302 | c.5457C>T p.S1819= | Silent (SNP) | VAF 69/238 reads (29%) | called by muse, mutect2, varscan2
- MBTPS2 | c.765G>A p.G255= | Silent (SNP) | VAF 62/343 reads (18%) | called by muse, mutect2, varscan2
- MINDY2 | c.714G>T p.P238= | Silent (SNP) | VAF 33/102 reads (32%) | catalogued as COSV100376321; called by muse, mutect2
- MUC16 | c.8652G>T p.G2884= | Silent (SNP) | VAF 10/88 reads (11%) | catalogued as rs371075905, COSV67464770; called by mutect2, varscan2
- MYOC | c.207A>T p.S69= | Silent (SNP) | VAF 34/131 reads (26%) | called by muse, mutect2, varscan2
- MYPN | c.438C>T p.S146= | Silent (SNP) | VAF 90/308 reads (29%) | catalogued as COSV62741593; called by muse, mutect2, varscan2
- OR6N1 | c.462T>A p.A154= | Silent (SNP) | VAF 45/277 reads (16%) | called by muse, mutect2, varscan2
- PEG10 | c.813C>A p.T271= (on ENST00000482108 / NM_001040152.2; = p.T305= on NM_015068.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 91/278 reads (33%) | catalogued as COSV71787988; called by muse, mutect2, varscan2
- PKD1L1 | c.3963C>T p.N1321= | Silent (SNP) | VAF 29/82 reads (35%) | called by muse, mutect2, varscan2
- PLCE1 | c.2163C>T p.S721= | Silent (SNP) | VAF 110/310 reads (35%) | catalogued as rs377278909; called by muse, mutect2, varscan2
- PLXDC2 | c.624C>A p.P208= | Silent (SNP) | VAF 20/143 reads (14%) | called by muse, mutect2, varscan2
- POLA1 | c.1614C>A p.V538= | Silent (SNP) | VAF 25/148 reads (17%) | catalogued as COSV66891669; called by muse, mutect2, varscan2
- PTPRG | c.1437C>A p.T479= | Silent (SNP) | VAF 24/103 reads (23%) | catalogued as rs1380566146; called by muse, varscan2
- RANBP17 | c.675C>T p.C225= | Silent (SNP) | VAF 115/285 reads (40%) | catalogued as COSV66652761; called by muse, mutect2, varscan2
- RAVER2 | c.1542G>T p.T514= (on ENST00000294428 / NM_001366165.1; = p.T501= on NM_018211.4) | Silent (SNP) | VAF 86/391 reads (22%) | catalogued as rs752822626, COSV99605693; called by muse, mutect2, varscan2
- RXFP1 | c.30C>T p.I10= | Silent (SNP) | VAF 6/51 reads (12%) | called by muse, mutect2, varscan2
- RYR2 | c.13092C>G p.T4364= | Silent (SNP) | VAF 17/69 reads (25%) | catalogued as rs770232323, COSV63662655; called by muse, mutect2, varscan2
- SLC22A7 | c.1026G>T p.R342= (on ENST00000372585 / NM_153320.2; = p.R340= on NM_006672.3) | Silent (SNP) | VAF 19/207 reads (9%) | called by muse, mutect2
- SMC6 | c.858T>C p.I286= | Silent (SNP) | VAF 5/97 reads (5%) | called by muse, mutect2
- STXBP6 | c.258C>T p.R86= | Silent (SNP) | VAF 10/146 reads (7%) | called by muse, mutect2
- TPO | c.1638A>T p.P546= | Silent (SNP) | VAF 37/298 reads (12%) | called by muse, mutect2, varscan2
- TRAPPC12 | c.456C>G p.P152= | Silent (SNP) | VAF 44/406 reads (11%) | called by muse, mutect2, varscan2
- TRPA1 | c.777G>A p.L259= | Silent (SNP) | VAF 38/269 reads (14%) | called by muse, mutect2, varscan2
- TRPC7 | c.1287C>T p.F429= | Silent (SNP) | VAF 167/380 reads (44%) | called by muse, mutect2, varscan2
- TRPM6 | c.4761G>A p.K1587= | Silent (SNP) | VAF 95/314 reads (30%) | catalogued as COSV62511095; called by muse, mutect2, varscan2
- URB1 | c.6777G>T p.V2259= | Silent (SNP) | VAF 54/198 reads (27%) | called by muse, mutect2, varscan2
- WASHC5 | c.3042A>T p.T1014= | Silent (SNP) | VAF 117/445 reads (26%) | called by muse, mutect2, varscan2
- ZFHX4 | c.1659C>A p.G553= | Silent (SNP) | VAF 39/206 reads (19%) | called by muse, mutect2, varscan2
- ZNF112 | c.2700A>G p.S900= (on ENST00000337401 / NM_001083335.2; = p.S894= on NM_013380.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 4/54 reads (7%) | catalogued as rs1215656422; called by muse, mutect2
- ZNF787 | c.153G>T p.A51= | Silent (SNP) | VAF 3/19 reads (16%) | called by muse, mutect2
- ACTB | c.363+22C>A | Intron (SNP) | VAF 94/259 reads (36%) | called by muse, mutect2, varscan2
- CPNE2 | c.927+976G>T | Intron (SNP) | VAF 32/78 reads (41%) | called by muse, mutect2, varscan2
- CTCFL | c.1841-1640C>A | Intron (SNP) | VAF 15/56 reads (27%) | called by muse, mutect2, varscan2
- FAM157A | n.4G>T | RNA (SNP) | VAF 145/528 reads (27%) | called by muse, mutect2, varscan2
- FAM90A20P | n.635G>T | RNA (SNP) | VAF 148/368 reads (40%) | catalogued as rs200615864; called by muse, mutect2, varscan2
- FMO6P | n.1389C>T | RNA (SNP) | VAF 60/310 reads (19%) | catalogued as rs749790829; called by muse, mutect2, varscan2
- FRMD1 | chr6:168081486 C>T | 5'Flank (SNP) | VAF 48/133 reads (36%) | catalogued as rs1306694337; called by muse, mutect2, varscan2
- GFOD1 | c.*3847G>T | 3'UTR (SNP) | VAF 10/94 reads (11%) | called by muse, mutect2, varscan2
- HLA-F | chr6:29727984 C>T | 3'Flank (SNP) | VAF 49/129 reads (38%) | called by muse, mutect2, varscan2
- HSP90AA4P | n.2006C>A | RNA (SNP) | VAF 41/241 reads (17%) | called by muse, mutect2, varscan2
- IGKV1D-42 | c.-6C>A | 5'UTR (SNP) | VAF 95/315 reads (30%) | called by muse, mutect2, varscan2
- IL7 | c.-7G>T | 5'UTR (SNP) | VAF 29/173 reads (17%) | called by muse, mutect2, varscan2
- LINC01956 | n.430G>T | RNA (SNP) | VAF 16/158 reads (10%) | called by muse, mutect2
- LINC02312 | n.602del | RNA (DEL) | VAF 107/326 reads (33%) | called by mutect2, pindel, varscan2
- LMX1B | c.886+27G>T | Intron (SNP) | VAF 48/130 reads (37%) | called by muse, mutect2, varscan2
- MARCHF1 | c.242+525C>A | Intron (SNP) | VAF 22/88 reads (25%) | called by muse, mutect2, varscan2
- MIR515-2 | n.52A>G | RNA (SNP) | VAF 5/45 reads (11%) | called by muse, mutect2, varscan2
- MIR518A1 | n.50A>T | RNA (SNP) | VAF 36/155 reads (23%) | called by muse, mutect2, varscan2
- MPDU1 | chr17:7583760 G>T | 5'Flank (SNP) | VAF 30/265 reads (11%) | catalogued as rs754071409; called by muse, mutect2, varscan2
- MTFR2 | c.63+1559A>T | Intron (SNP) | VAF 15/64 reads (23%) | called by muse, mutect2, varscan2
- MYH6 | c.1581+76C>A | Intron (SNP) | VAF 58/132 reads (44%) | called by muse, mutect2
- NSFL1C | c.279-600G>T | Intron (SNP) | VAF 53/266 reads (20%) | called by muse, mutect2, varscan2
- ODF2 | chr9:128456189 C>A | 5'Flank (SNP) | VAF 42/384 reads (11%) | catalogued as rs1270889321; called by muse, mutect2, varscan2
- OFCC1 | n.566T>C | RNA (SNP) | VAF 11/149 reads (7%) | called by muse, mutect2
- PIPSL | n.1897C>A | RNA (SNP) | VAF 95/347 reads (27%) | called by muse, mutect2, varscan2
- PPM1J | c.*17C>A | 3'UTR (SNP) | VAF 6/19 reads (32%) | called by muse, mutect2
- PRRG3 | c.-7G>T | 5'UTR (SNP) | VAF 18/124 reads (15%) | catalogued as COSV100948655; called by muse, mutect2, varscan2
- PTMS | c.-5del | 5'UTR (DEL) | VAF 6/24 reads (25%) | called by mutect2, pindel, varscan2
- SLC19A3 | c.*1324G>T | 3'UTR (SNP) | VAF 33/100 reads (33%) | called by muse, mutect2, varscan2
- SLC47A2 | c.225+42C>A | Intron (SNP) | VAF 28/230 reads (12%) | called by muse, mutect2, varscan2
- SMAP1 | c.-49G>A | 5'UTR (SNP) | VAF 21/226 reads (9%) | called by muse, mutect2
- SNORD115-37 | n.23A>G | RNA (SNP) | VAF 25/121 reads (21%) | called by muse, mutect2, varscan2
- TEX37 | c.*2A>G | 3'UTR (SNP) | VAF 9/69 reads (13%) | catalogued as rs1220931737; called by muse, varscan2
- UNC93B1 | c.96+40G>T | Intron (SNP) | VAF 45/159 reads (28%) | called by muse, mutect2, varscan2
- VAPB | c.*2516G>T | 3'UTR (SNP) | VAF 25/133 reads (19%) | called by muse, mutect2, varscan2
- WASF4P | n.224T>A | RNA (SNP) | VAF 62/330 reads (19%) | called by muse, mutect2, varscan2
- ZNF182 | c.-23+48G>T | Intron (SNP) | VAF 37/196 reads (19%) | called by muse, mutect2, varscan2
- ZNF735 | c.-28C>T | 5'UTR (SNP) | VAF 113/319 reads (35%) | called by muse, mutect2, varscan2
- ZSCAN32 | c.839-863G>T | Intron (SNP) | VAF 44/554 reads (8%) | catalogued as COSV59235543; called by muse, mutect2
